TCGA case TCGA-P5-A5F0 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7eb5d055-e1c8-4b93-9205-a49a6e79dfd4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 33 years; Vital status: Alive.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 33.3 years (12,157 days); Year of diagnosis: 2012; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 287 days; First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 23 days; Days to treatment end: 70 days; Treatment dose: 60 Gy; Treatment outcome: Partial Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine + Procarbazine + Vincristine; Days to treatment start: 89 days; Days to treatment end: 287 days; Treatment outcome: Partial Response.
   Recorded as not given: Antiseizure Treatment, preoperative; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.

Follow-up (3 entries)
- Days to follow up: 125 days; Disease response: With Tumor.
- Karnofsky performance status: 80.
- Follow-up contact recording only the day: day 287.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Motor / Movement Change / Seizure / Sensory Changes / Vision Changes.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-P5-A5F0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-P5-A5F0-01A-01-TS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-P5-A5F0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: Yes; History headaches: Yes; Symp changes mental status: No; Symp changes visual: Yes; Symp changes sensory: Yes; Symp changes motor movement: Yes; First symptom longest duration: > 181 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 287 days; disease-specific survival: no event (censored), 287 days; progression-free interval: no event (censored), 287 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-P5-A5F0-01A-11D-A288-01): tumor purity 0.76, ploidy 2, whole-genome doublings 0.
